FM case AD9723 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/95022879-30b8-4ac5-b9a8-8908894d8fb5

Male, 41.9 years: diagnosis not reported by GDC; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
